Gene-level copy-number profile of tumor specimen TCGA-97-7554-01A from TCGA case TCGA-97-7554, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 83.0 years (30,327 days).
Specimen TCGA-97-7554-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8660cd0d-39dd-43d6-9296-1868977e44f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-7554-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a06f1df7-aef2-4d3c-9c8c-e37368d0ca35

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 47; copy number 2: 503; copy number 3: 7,625; copy number 4: 15,364; copy number 5: 7,445; copy number 6: 13,579; copy number 7: 3,839; copy number 8: 5,016; copy number 9: 3,956; copy number 10: 995; copy number 11: 758; copy number 12: 634; copy number 14: 31; copy number 19: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-7554-01A-11D-2035-01): tumor purity 0.29, ploidy 5.21, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:14,169,746–14,778,002, 17 genes: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6,058 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 9 (broad region; genes not listed).
- chr2:74,123,965–77,593,319, 87 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr6:18,120,440–18,468,870, 10 genes, copy number 10: NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B.
- chr6:21,664,185–22,654,455, 1 gene, copy number 11 (within-gene range 5–11): CASC15.
- chr6:22,085,544–41,736,259, 839 genes, copy number 10–11 (broad region; genes not listed).
- chr11:167,784–36,697,867, 915 genes, copy number 9 (broad region; genes not listed).
- chr12:22,063,773–22,437,041, 1 gene, copy number 11 (within-gene range 6–11): ST8SIA1.
- chr12:22,195,469–26,421,462, 65 genes, copy number 9–14 (broad region; genes not listed).
- chr12:26,335,864–26,373,733, 2 genes, copy number 9: AC055720.2, RNA5SP354.
- chr12:28,978,584–30,492,302, 22 genes, copy number 10: AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1.
- chr14:31,100,112–31,207,804, 1 gene, copy number 9 (within-gene range 7–9): HECTD1.
- chr14:31,142,939–50,831,162, 289 genes, copy number 9–19 (within-gene range 7–19) (broad region; genes not listed).
- chr15:19,878,555–23,856,375, 176 genes, copy number 9 (broad region; genes not listed).
- chr18:25,953,216–26,657,401, 17 genes, copy number 9: AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:26,685,954–26,832,432, 5 genes, copy number 9: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2.
- chr21:10,328,411–30,829,759, 314 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
